Gene-level copy-number profile of tumor specimen ALCH-AETD-TTP1-A from ALCHEMIST case ALCH-AETD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.2 years (16,866 days).
Specimen ALCH-AETD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7efbf3c0-4e3b-479c-a1a6-1d8f8f522d6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AETD-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/97f01584-f05b-49ba-ad67-175d1d4f8006

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 802; copy number 2: 57,364; copy number 3: 165; copy number 4: 16; copy number 5: 2; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,391,707, 5 genes (within-gene range 0–2): AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2.
- chr1:2,425,980–2,547,460, 6 genes: PLCH2, AL139246.1, AL139246.4, PANK4, HES5, AL139246.5.
- chr1:10,616,836–10,617,115, 1 gene (within-gene range 0–2): RN7SL614P.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–1): AL139423.1.
- chr15:25,170,723–25,225,284, 30 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr16:1,221,651–1,230,184, 3 genes (within-gene range 0–2): TPSG1, AC120498.10, TPSB2.
- chr17:79,132,722–79,136,402, 1 gene (within-gene range 0–2): AC021534.1.
- chr20:62,302,093–62,308,862, 2 genes (within-gene range 0–1): ADRM1, AL354836.1.
- chr22:19,018,043–19,018,916, 1 gene (within-gene range 0–2): AC000095.1.
- chr22:19,031,564–19,034,564, 1 gene: CA15P1.
- chr22:19,045,256–19,048,375, 2 genes (within-gene range 0–2): Y_RNA, DGCR11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:137,554,444–137,590,512, 2 genes, copy number 6: DPH7, ZMYND19.
- chr20:62,877,738–62,937,952, 2 genes, copy number 5: DIDO1, AL117379.1.

Autosomal genes at a single copy (total copy number 1): 802. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
